Somatic mutation profile of tumor specimen MMRF_2722_1_BM_CD138pos (aliquot MMRF_2722_1_BM_CD138pos_T1_KHS5U_L14825) from MMRF case MMRF_2722, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2722_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54d05baf-90fa-4260-865f-51f2ce9c8527.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2722_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2722_1_PB_WBC_C2_KHS5U_L14826; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24f02b17-0477-4740-b633-c8ddda693a60

The open-access MAF lists 62 somatic variants for this specimen: 21 protein-altering or splice-affecting, 9 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 21, Missense Mutation 20, Silent 9, Intron 4, 5'UTR 4, 5'Flank 2, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 50/56 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV66706044; called by muse, mutect2, varscan2
- CHRDL2 | c.143C>A p.P48H | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55222961; called by muse, mutect2, varscan2
- MRPL38 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); catalogued as rs777199413; called by muse, mutect2, varscan2
- SCNN1D | c.1085G>A p.R362Q (on ENST00000338555; = p.R526Q on NM_001130413.4) | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs777158918; called by muse, mutect2, varscan2
- SH3GL2 | c.785G>A p.S262N | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs1182267155; called by muse, mutect2, varscan2
- SLC2A10 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs1568986425; called by muse, mutect2, varscan2
- TANC2 | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV67343826; called by muse, mutect2
- TLCD3B | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.227); catalogued as rs1030821202, COSV54227234; called by muse, mutect2, varscan2
- ARHGEF10 | c.3049T>C p.F1017L (on ENST00000398564; = p.F992L on NM_014629.4) | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BBX | c.2537C>T p.A846V (on ENST00000325805 / NM_001142568.3; = p.A816V on NM_020235.7) | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CCDC28B | c.548+5C>G | Splice Region (SNP) | VAF 20/39 reads (51%) | called by muse, mutect2, varscan2
- CD93 | c.239T>G p.L80R | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFTR | c.4010T>A p.F1337Y | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCAF13 | c.335T>G p.V112G | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FAM172A | c.1003A>T p.I335F | Missense Mutation (SNP) | VAF 15/272 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2
- HSPA5 | c.1891A>C p.I631L | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- LRP2 | c.9833A>T p.D3278V | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- NOS3 | c.142C>G p.P48A | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.051); called by mutect2, varscan2
- SBK3 | c.40C>A p.P14T | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIPA1 | c.1862T>C p.V621A | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- SUPT7L | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- ANKRD33B | c.162G>C p.S54= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs1308018159, COSV56977440; called by muse, mutect2, varscan2
- ATP10B | c.2106A>T p.A702= | Silent (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- DCHS1 | c.3171G>T p.R1057= | Silent (SNP) | VAF 75/163 reads (46%) | called by muse, mutect2, varscan2
- FAM155B | c.231C>A p.A77= | Silent (SNP) | VAF 23/24 reads (96%) | called by muse, mutect2, varscan2
- MARCHF7 | c.1770C>A p.A590= | Silent (SNP) | VAF 64/130 reads (49%) | called by muse, mutect2, varscan2
- NMUR2 | c.177G>A p.G59= | Silent (SNP) | VAF 49/115 reads (43%) | called by muse, mutect2, varscan2
- SYT15 | c.528C>A p.A176= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as rs1278649550; called by mutect2, varscan2
- TLR6 | c.510T>C p.H170= | Silent (SNP) | VAF 37/81 reads (46%) | called by muse, mutect2, varscan2
- ZBED1 | c.435C>T p.D145= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs777092860; called by muse, mutect2, varscan2
- ANKRD18B | c.*555A>G | 3'UTR (SNP) | VAF 28/52 reads (54%) | called by muse, mutect2, varscan2
- AURKB | c.*30G>A | 3'UTR (SNP) | VAF 19/36 reads (53%) | called by muse, mutect2, varscan2
- CAVIN4 | c.*122_*130del | 3'UTR (DEL) | VAF 9/21 reads (43%) | called by mutect2, varscan2
- CEP290 | c.2817+129C>G | Intron (SNP) | VAF 4/9 reads (44%) | called by muse, varscan2
- DDI1 | c.*554A>C | 3'UTR (SNP) | VAF 30/67 reads (45%) | catalogued as rs945157068; called by muse, mutect2, varscan2
- DYNC1LI2 | c.*1336T>C | 3'UTR (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- FNIP2 | c.*1289A>T | 3'UTR (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- GNB3 | chr12:6851292 T>C | 3'Flank (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2
- GTF2A1 | c.*1784G>C | 3'UTR (SNP) | VAF 21/37 reads (57%) | called by muse, mutect2, varscan2
- GTF2E1 | c.*841G>T | 3'UTR (SNP) | VAF 24/48 reads (50%) | called by muse, mutect2, varscan2
- HOXC11 | c.*1146G>T | 3'UTR (SNP) | VAF 41/83 reads (49%) | catalogued as rs1370127753; called by muse, mutect2, varscan2
- KCNAB2 | c.416-70A>G | Intron (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- LDHAL6A | c.*442C>G | 3'UTR (SNP) | VAF 3/15 reads (20%) | called by mutect2, varscan2
- MAPK8IP3 | c.744+112C>T | Intron (SNP) | VAF 6/11 reads (55%) | catalogued as rs1169631942; called by muse, mutect2, varscan2
- MED1 | c.*42A>C | 3'UTR (SNP) | VAF 14/31 reads (45%) | called by muse, mutect2, varscan2
- NEDD4L | c.297+63C>T | Intron (SNP) | VAF 12/21 reads (57%) | catalogued as rs916638076; called by muse, mutect2, varscan2
- NR2F2 | c.-171C>G | 5'UTR (SNP) | VAF 8/24 reads (33%) | called by mutect2, varscan2
- PDSS2 | c.*1378C>T | 3'UTR (SNP) | VAF 31/33 reads (94%) | called by muse, mutect2, varscan2
- PGGHG | c.-7C>G | 5'UTR (SNP) | VAF 45/97 reads (46%) | called by muse, mutect2, varscan2
- PPP4C | c.*136G>A | 3'UTR (SNP) | VAF 11/20 reads (55%) | catalogued as rs1186873283; called by muse, mutect2, varscan2
- RMI1 | c.*712T>C | 3'UTR (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2, varscan2
- RPS29 | chr14:49586454 T>A | 5'Flank (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
- SLC28A3 | c.*2139A>G | 3'UTR (SNP) | VAF 60/118 reads (51%) | called by muse, mutect2, varscan2
- SLC7A6 | c.*2303T>C | 3'UTR (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- STEAP2 | c.*3498A>T | 3'UTR (SNP) | VAF 5/91 reads (5%) | called by muse, mutect2
- SUB1 | c.*1245C>T | 3'UTR (SNP) | VAF 65/128 reads (51%) | catalogued as rs1421341228; called by muse, mutect2, varscan2
- TASP1 | c.*510C>A | 3'UTR (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- WAC | c.-320G>A | 5'UTR (SNP) | VAF 10/12 reads (83%) | catalogued as rs994503619; called by muse, varscan2
- WEE1 | c.-79G>A | 5'UTR (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- WRNIP1 | c.*766G>T | 3'UTR (SNP) | VAF 63/115 reads (55%) | called by muse, mutect2, varscan2
- YKT6 | c.*269G>A | 3'UTR (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- ZNF606 | chr19:58005434 G>C | 5'Flank (SNP) | VAF 32/55 reads (58%) | catalogued as rs1276437676; called by muse, mutect2, varscan2
